CCDI case PBBPVS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/1949d61b-071a-4ad0-99ae-cc44093e7374

Demographics
Sex at birth: female; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 17.2 years (6,292 days).

Biospecimens (3 samples)
- Sample 0DELJ3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DELJ8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DELKO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
